Somatic mutation profile of tumor specimen BA2224D (aliquot aq-BA2224D) from BEATAML1.0 case 2202, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.6 years (22,871 days).
Specimen BA2224D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dbf4d5d3-b77a-4e7e-bdc8-4171ebbffa4b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2010D (Solid Tissue Normal), aliquot aq-BA2010D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/57f0ff1e-a130-44fd-8a45-bc27ff235c64

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TTN | c.49910G>T p.C16637F (on ENST00000591111; = p.C9213F on NM_003319.4) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | PolyPhen benign (0.173); catalogued as rs1213616804; called by muse, mutect2
- HDLBP | c.3334G>T p.A1112S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.117); called by muse, mutect2
- VWA5B2 | c.943C>A p.Q315K | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.931); called by muse, mutect2
- ZBTB22 | c.361G>T p.A121S | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.237); called by muse, mutect2
- COL12A1 | c.6750G>T p.V2250= | Silent (SNP) | VAF 5/28 reads (18%) | called by muse, mutect2
- DSC3 | c.915C>T p.T305= | Silent (SNP) | VAF 28/73 reads (38%) | called by muse, mutect2, varscan2
- EPHB2 | c.1428+47C>A | Intron (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2
